Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7925, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7925-01A (Primary Tumor).

[page 1 of 5]
Patient Results

Some results may not be shown for all available charts for performed dates from

Criteria for selection:

Path Report

Final

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. :

Final Diagnosis(es):

- (A) Falciform ligament, biopsy: Vascularized fibroadipose tissue, negative for malignancy.
- (B) Lymph node, posterior portal area, biopsy: One lymph node, negative for metastatic malignancy (0/1).
- (C) Lymph nodes, hepatoduodenal, biopsy: Two lymph nodes, positive for metastatic malignancy (2/2).
- (D) Common bile duct margin, excision: Negative for malignancy.
- (E) Pancreatic duct margin, excision:
- 1) Negative for malignancy.
- 2) Chronic pancreatitis.
- (F) Pancreas, gallbladder, jejunum, duodenum, stomach, Whipple procedure:
- 1) Invasive adenocarcinoma, moderately differentiated, of pancreas.
- 2) Tumor size: 4.7 cm in greatest diameter.
- 3) All surgical margins are negative for involvement by carcinoma.
- 4) Sixteen lymph nodes, negative for metastatic malignancy (0/16).
- 5) Pathologic staging: pT3pN1.
- 6) Stomach, jejunum, duodenum and gallbladder with no histopathologic abnormality.
- 7) Please see Synoptic report (below) for complete summary.
- (G) Lymph node, superior mesenteric artery region, biopsy: Fragments of benign pancreatic parenchyma; negative for malignancy.
- Synoptic Report:
- Specimens: Head of pancreas, duodenum, stomach, common bile duct, gallbladder.
- Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy.
- Tumor Site: Pancreatic head.
- Tumor Size:
- Greatest Dimension: 4.7 cm.
- Additional Dimensions: 4.1 x 3.8 cm.
- Histologic Type: Ductal adenocarcinoma.
- Histologic Grade: G2: Moderately differentiated.
- Microscopic Tumor Extension:
- Carcinoma in situ.

Printed from: Default

Page: 1 of 6

[page 2 of 5]
Patient Results

Some results may not be shown for all available charts for performed dates from

Final

Tumor invades duodenal wall.

Margins:

Margins uninvolved by invasive carcinoma:

Proximal and distal, pancreatic, uncinate and common bile duct.

Treatment Effect: Not known.

Lymphovascular Invasion: Not identified.

Perineural Invasion: Present.

Pathologic Staging:

Primary Tumor: PT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery.

Regional Lymph Nodes: pN1: Regional lymph node metastasis.

Number of Lymph Nodes Examined: 19

Number of Lymph Nodes Involved: 2

Distant Metastasis: Not applicable.

Additional Pathologic Findings:

Pancreatic intraepithelial neoplasia (highest grade: PanIN3).

Chronic pancreatitis.

Comments:

This case has been reviewed and the diagnosis approved by consulting departmental surgical pathology staff.

'The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist'

Specimen(s) Received:

A: Falciform ligament

B: Posterior portal LN

C: Hepatoduodenal LN

D: Common bile duct margins

E: Pancreatic duct

F: Stomach, pancreas, duodenum, gallbladder, jejunum (Whipple specimen)

G: SMA LN

Clinical History:

Pancreatic adenocarcinoma.

Intraoperative Consultation:

Time Received:

Time Reported:

FSD1: Common bile duct margins: Inflammation with atypia, favor reactive (1 block).

FSE1: Pancreatic duct: Epithelial atypia; no invasive

Printed from: Default

Page: 2 of 6

[page 3 of 5]
Patient Results

Some results may not be shown for all available charts for performed dates from

Final

malignancy (1 block).

Gross Description:

(A) (falciform ligament) Received in formalin is a strip of soft yellow lobular fat with a central of solid gray-white fibrous tissue, consistent with falciform ligament. The specimen measures 9.0 x 8.0 X 1.0 cm in greatest dimensions. The entire fibrous cord is submitted in cassette A1.

(B) (posterior portal lymph node) Received in formalin is a tan-pink rubbery ovoid lymph node that measures 1.5 x 0.6 x 0.3 cm in greatest dimensions. The specimen is serially sectioned perpendicular to the long axis and entirely submitted in cassette B1.

(C) (hepatoduodenal lymph node) Received in formalin are two tan-red rubbery ovoid lymph nodes, the larger of which measures 1.0 x 0.8 x 0.7 cm in greatest dimensions, and the smaller of which measures 1.8 x 1.0 x 0.8 cm in greatest dimensions. The smaller lymph node is bisected and entirely submitted in cassette C1. The larger lymph node is serially sectioned and entirely submitted in cassette C2.

(D) (common bile duct margins) Received fresh for frozen section is a portion of tan-gray bile duct which measures 0.4 cm in length and 1.5 cm in diameter. The specimen is entirely submitted for frozen section in cassette FSD1.

(E) (pancreatic duct) Received fresh for frozen section is portion of tan soft tissue which measures 3.0 x 1.0 x 0.5 cm in greatest dimensions. A stitch marks the area of interest. The specimen is divided and entirely submitted for frozen section in cassettes FSE1 and FSE2.

(F) (stomach, pancreas, duodenum, gallbladder, jejunum, Whipple specimen)

Specimen components and dimensions: Received fresh is a Whipple procedure specimen consisting of stomach, small bowel, gallbladder and head of pancreas portion. The portion of stomach measures 7.0 cm in diameter at the gastric margin, 10.0 cm in length along the greater curvature, and 3.7 cm in length along the lesser curvature. The segment of duodenum/jejunum measures 21.5 cm in length and 3.6 cm in greatest diameter at the distal stapled margin. There is an attached, unopened gallbladder that measures 9.0 x 3.5 x 1.8 cm. The stented bile duct protrudes through the ampulla. The head of the pancreas measures 4.0 cm from the interface with the duodenum to the pancreatic margin, 4.2 cm from retroperitoneal to anterior aspect, and 5.2 cm from the superior to the inferior-most aspect of the uncus margin. The pancreatic resection margin is inked black. The anterior surface is inked orange, the uncinate

[page 4 of 5]
Patient Results

Some results may not be shown for all available charts for performed dates from

Final

margin is inked green, the posterior margin is inked blue and the area near the vessels is inked red.

Size, appearance, and location of tumor: The tumor appears solid gray-white, lobulated, and occupies almost the entire head of the pancreas. The tumor measures 3.8 cm x 4.7 cm x 4.1 cm in greatest dimensions.

Gross impression of invasive growth: The tumor appears to envelop the bile duct, however, no invasion is grossly identified. The tumor appears to abut the serosa of the duodenum at the ampulla, however, no gross invasion of the ampulla or the duodenal mucosa is identified.

Closest resection margins and distance: The tumor is grossly within 0.2 cm of the pancreatic resection margin and 0.2 cm of the uncinate margin at the central superior aspect. The tumor is present at 0.2 cm of the area near the vessels and within 0.2 cm of the anterior surface.

Other findings: There is scant tan soft lobular pancreatic parenchyma near the retroperitoneal region, with the tumor occupying at least 75% of the total volume of the pancreatic duct area.

Uninvolved tissues: The gallbladder is red-black on its serosal surfaces, has a boggy 0.2 to 0.5 cm thick wall with dark brown velvety mucosal surfaces and mild focal cholesterosis. The gastric mucosa is tan, smooth with focal rugae. The pyloric sphincter is thick and no polyps or mass are identified. The duodenal mucosa is tightly folded, tan-brown without polyp or mass.

Lymph nodes attached: Two tan rubbery lymph nodes from the gastro-omental region measure 0.4 and 0.7 cm in greatest dimension. Six lymph nodes from the pericaval region are gray-tan, rubbery and measure 0.4 to 1.0 cm in greatest dimension.

Blocks submitted:

F1 - pancreatic margin en face

F2-F3 posterior area en face

F4 area near vessels en face

F5 - anterior area near tumor en face

F6-F8 - uncinate margin divided in sequence from posterior to anterior all en face

F9-F10 - ampulla, bile duct, pancreas and duodenum sections

F11 - transverse section of bile duct near the vessels

F12-F13 - full thickness sagittal section of pancreatic head

F14-F15 - gastric margin divided

F16 - representative sections of stomach to include pyloric sphincter

F17 - sections of gallbladder

F18 - sections of duodenum

F19 - distal margin

[page 5 of 5]
Patient Results

Some results may not be shown for all available charts for performed dates from

Surgical Pathology (Copath)

Final

F20 - two lymph nodes from gastro-omental fat

F21 - six paracaval lymph nodes

(G) (superior mesenteric artery lymph node) Received in formalin on Telfa is an ovoid tan-red and focally friable rubbery tissue fragment that measures 0.6 cm in greatest dimension. It is submitted entirely intact in cassette G1.

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at the

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file 616f088d-b9c4-4b8a-807f-cf49a886cd9f (TCGA-HZ-7925.CFB61832-A6B4-4BDF-9E3F-2F35BE00601A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).